Gene-level copy-number profile of tumor specimen C3L-00422-01 (profiled together with C3L-00422-02) from CPTAC case C3L-00422, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 35.2 years (12,844 days).
Specimen C3L-00422-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5cfd2d85-0850-42f9-81d2-5d0c6582f7a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00422-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/87b5bb1c-489a-4f38-b213-5b0293954c92

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 4; copy number 2: 1; copy number 3: 22; copy number 4: 27,277; copy number 5: 959; copy number 6: 18,702; copy number 7: 248; copy number 8: 10,885; copy number 9: 268; copy number 14: 1; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,505,430–161,524,013, 1 gene (within-gene range 0–1): FCGR2A.
- chr1:161,524,540–161,526,894, 1 gene (within-gene range 0–1): HSPA6.
- chr1:161,556,290–161,557,078, 1 gene (within-gene range 0–1): AL590385.1.
- chr1:248,590,487–248,597,700, 1 gene (within-gene range 0–2): OR2T10.
- chr1:248,601,416–248,635,091, 2 genes: AC098483.2, OR2T11.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 270 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–3,536,094, 87 genes, copy number 9 (broad region; genes not listed).
- chr8:12,425,614–12,436,343, 1 gene, copy number 23: FAM86B2.
- chr9:64,810,865–64,811,429, 1 gene, copy number 14: BNIP3P4.
- chr11:86,649–3,422,496, 181 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
